Somatic mutation profile of tumor specimen TCGA-S9-A6U8-01A (aliquot TCGA-S9-A6U8-01A-21D-A33T-08) from TCGA case TCGA-S9-A6U8, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 24.8 years (9,044 days).
Specimen TCGA-S9-A6U8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de316d6f-0673-46fa-8dc5-7e5f8d03908f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6U8-10A (Blood Derived Normal), aliquot TCGA-S9-A6U8-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c12c2781-70a9-40cb-883a-6af72829cb52

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 14, Silent 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 67/168 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 105/139 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAN | c.7462C>T p.P2488S (on ENST00000560601 / NM_001369268.1; = p.P2450S on NM_013227.3) | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375041472; called by muse, mutect2, varscan2
- ATRX | c.6515A>G p.E2172G | Missense Mutation (SNP) | VAF 93/134 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64871256, COSV64876122; called by muse, mutect2, varscan2
- BTNL8 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); catalogued as rs769402531, COSV51458948; called by muse, mutect2, varscan2
- CBY2 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1262275227, COSV60118620; called by muse, mutect2, varscan2
- CR1 | c.4033G>T p.E1345* | Nonsense Mutation (SNP) | VAF 88/266 reads (33%) | catalogued as COSV100887649; called by muse, mutect2, varscan2
- CSMD3 | c.9086G>A p.G3029D (on ENST00000297405 / NM_001363185.1; = p.G2860D on NM_052900.3) | Missense Mutation (SNP) | VAF 71/191 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99836076; called by muse, mutect2, varscan2
- E2F2 | c.359C>T p.T120I | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62276986; called by muse, mutect2, varscan2
- MUC16 | c.14291C>T p.P4764L | Missense Mutation (SNP) | VAF 71/180 reads (39%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs371360570; called by muse, mutect2, varscan2
- NKD1 | c.809C>G p.S270C | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99194061; called by muse, mutect2, varscan2
- SIGLEC9 | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs753561495, COSV51582423, COSV51585007; called by muse, mutect2, varscan2
- SMARCA2 | c.2432G>A p.R811H | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61807383, COSV61807508; called by muse, mutect2, varscan2
- TENM3 | c.5044G>T p.D1682Y | Missense Mutation (SNP) | VAF 13/293 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV101305166, COSV69303933; called by muse, mutect2
- TNRC18 | c.6564C>G p.Y2188* | Nonsense Mutation (SNP) | VAF 4/58 reads (7%) | catalogued as COSV100078884; called by muse, mutect2
- TRIP11 | c.1723C>T p.H575Y | Missense Mutation (SNP) | VAF 75/204 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs916889656, COSV99970751; called by muse, mutect2, varscan2
- KIAA1755 | c.63C>T p.F21= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs773620104, COSV104379070, COSV99642124; called by muse, mutect2, varscan2
- NUTM2G | c.213C>T p.R71= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs557391138, COSV100672873; called by muse, mutect2, varscan2
- SORD | c.519A>G p.G173= | Silent (SNP) | VAF 54/183 reads (30%) | catalogued as COSV99980591; called by muse, mutect2, varscan2
